Gene-level copy-number profile of tumor specimen C3L-08313-05 from CPTAC case C3L-08313, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.3 years (26,053 days).
Specimen C3L-08313-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b34b8296-5f56-4269-9ee4-6d6a53df883e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08313-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/2b3930f5-7231-4b72-ae2c-9b349179a208

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 307; copy number 2: 14,645; copy number 3: 28,280; copy number 4: 10,837; copy number 5: 1,446; copy number 6: 924; copy number 7: 848; copy number 8: 67; copy number 9: 326; copy number 10: 350; copy number 11: 17; copy number 12: 74; copy number 13: 5; copy number 16: 5; copy number 18: 7; copy number 20: 5; copy number 26: 17; copy number 27: 19; copy number 28: 1; copy number 29: 2; copy number 30: 8; copy number 32: 3; copy number 39: 2; copy number 50: 3; copy number 51: 57; copy number 62: 1; copy number 68: 1; copy number 76: 10; copy number 79: 9; copy number 88: 3; copy number 96: 2; copy number 97: 3; copy number 112: 15; copy number 126: 3; copy number 127: 2; copy number 130: 8; copy number 138: 1; copy number 140: 4; copy number 144: 3; copy number 160: 18; copy number 168: 12; copy number 180: 4; copy number 201: 1; copy number 206: 3; copy number 210: 11; copy number 220: 11; copy number 239: 2; copy number 241: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–3): AC104164.2, MIR548BB.
- chr4:91,108,023–91,112,790, 1 gene (within-gene range 0–3): AC004054.1.
- chr16:78,872,739–78,899,644, 3 genes (within-gene range 0–2): AC136603.1, AC027279.4, AC027279.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,944 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:8,461,703–11,642,788, 82 genes, copy number 7 (broad region; genes not listed).
- chr2:13,537,673–13,609,168, 1 gene, copy number 8: AC073062.1.
- chr2:68,679,601–68,826,833, 1 gene, copy number 7: ARHGAP25.
- chr5:58,198–45,895,970, 679 genes, copy number 7 (broad region; genes not listed).
- chr7:46,261,064–46,294,469, 1 gene, copy number 241: AC023669.1.
- chr7:54,621,025–55,344,958, 11 genes, copy number 220: RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr7:56,163,145–56,650,696, 26 genes, copy number 96–206: IFITM3P4, AC006970.1, CCNJP1, AC073136.1, AC073136.2, RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2, RNU6-1052P, AC092423.1, AC092447.7, AC092447.10, AC092447.4, RBM22P3, AC092447.8, NMD3P2, AC092447.3, AC092447.5, VN1R25P, AC092447.2, AC092447.6, AC092447.1, AC092447.9, TRIM60P16, AC095038.1.
- chr7:56,805,336–57,777,521, 53 genes, copy number 7–8: CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, MTCO3P4, AC099654.7, MTND4P5, MTND5P7, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2.
- chr7:102,456,238–106,112,576, 75 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:6,968,141–8,199,973, 81 genes, copy number 11–51 (within-gene range 3–51) (broad region; genes not listed).
- chr8:8,116,745–8,244,865, 6 genes, copy number 20–112: SNRPCP17, ENPP7P1, FAM85B, AC068020.1, FAM86B3P, ALG1L13P.
- chr8:8,414,204–9,436,205, 28 genes, copy number 27–138: AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P, CLDN23, AC087269.1, MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P.
- chr8:10,054,292–12,043,670, 66 genes, copy number 26–239 (within-gene range 1–239) (broad region; genes not listed).
- chr8:12,178,697–13,604,610, 45 genes, copy number 12–210 (within-gene range 12–261): ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2, RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1.
- chr8:121,954,640–122,733,804, 7 genes, copy number 7: AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2.
- chr8:123,219,967–134,979,279, 185 genes, copy number 7–16 (broad region; genes not listed).
- chr8:142,403,652–143,083,001, 33 genes, copy number 10–18: AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2, LY6E-DT, CDC42P3, LY6E, C8orf31, AK3P2, AC083982.1, LY6L.
- chr10:1,159,768–1,737,525, 4 genes, copy number 10 (within-gene range 1–10): LINC00200, ADARB2, AL392083.2, AL392083.1.
- chr10:1,526,637–5,632,566, 66 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr18:45,034–15,330,282, 367 genes, copy number 9–13 (broad region; genes not listed).
- chr20:52,671,735–59,948,680, 127 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 304. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
